Somatic mutation profile of tumor specimen TCGA-13-0884-01B (aliquot TCGA-13-0884-01B-01W-0494-09) from TCGA case TCGA-13-0884, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 39.8 years (14,538 days).
Specimen TCGA-13-0884-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abff1617-5ab3-4c00-8643-b843cf932e55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0884-10A (Blood Derived Normal), aliquot TCGA-13-0884-10A-01W-0494-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f34fc7ad-a21e-437c-901a-b764088e4fcc

The open-access MAF lists 120 somatic variants for this specimen: 96 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 21, Nonsense Mutation 7, Frame Shift Del 6, Splice Region 3, Splice Site 3, In Frame Del 2, 3'Flank 1, RNA 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP1 | c.1869G>A p.W623* | Nonsense Mutation (SNP) | VAF 40/95 reads (42%) | catalogued as rs878853221, COSV52851069; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACP2 | c.610T>C p.W204R | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV57042774; called by muse, mutect2, varscan2
- ACSM5 | c.1490T>C p.V497A | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59371919; called by muse, varscan2
- ACVR1 | c.1485G>C p.L495F | Missense Mutation (SNP) | VAF 81/317 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55119435; called by muse, mutect2, varscan2
- ADAMTS16 | c.764-2A>G p.X255_splice | Splice Site (SNP) | VAF 39/347 reads (11%) | catalogued as COSV56992275; called by muse, mutect2, varscan2
- AGFG1 | c.1568A>G p.K523R | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV59512349; called by muse, mutect2, varscan2
- ANKRD52 | c.2067G>A p.Q689= | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99921029; called by muse, mutect2, varscan2
- ANTXR2 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55018840; called by muse, mutect2, varscan2
- ATL2 | c.311G>C p.R104P | Missense Mutation (SNP) | VAF 62/468 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60052406, COSV60053137; called by muse, mutect2, varscan2
- ATRX | c.7205T>G p.I2402S | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV100970044; called by muse, mutect2
- BANK1 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV59843725; called by muse, mutect2, varscan2
- BIRC3 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs373514370; called by muse, mutect2, varscan2
- BMPR2 | c.2921G>C p.R974P | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65809966; called by muse, mutect2, varscan2
- BPIFB6 | c.303-2A>G p.X101_splice | Splice Site (SNP) | VAF 32/198 reads (16%) | catalogued as COSV62755404; called by muse, mutect2, varscan2
- C1orf127 | c.686G>C p.R229T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.382); catalogued as COSV65437524; called by muse, mutect2, varscan2
- C5 | c.1507-1G>C p.X503_splice | Splice Site (SNP) | VAF 6/25 reads (24%) | catalogued as COSV56328369; called by muse, mutect2, varscan2
- CA5B | c.10A>G p.M4V | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1455096191, COSV100590682; called by muse, mutect2
- CCDC33 | c.535A>T p.M179L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV58352717; called by muse, mutect2, varscan2
- CDSN | c.1572G>C p.E524D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV52538442; called by muse, mutect2, varscan2
- CLVS1 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 51/435 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57975873; called by muse, mutect2, varscan2
- CNBD2 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV62587099; called by muse, mutect2, varscan2
- COL4A4 | c.3219C>G p.N1073K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100306209; called by muse, mutect2, varscan2
- COL6A3 | c.9228A>C p.T3076= | Splice Region (SNP) | VAF 22/88 reads (25%) | catalogued as COSV55092368; called by muse, mutect2, varscan2
- CSMD3 | c.2588G>A p.G863E (on ENST00000297405 / NM_001363185.1; = p.G759E on NM_052900.3) | Missense Mutation (SNP) | VAF 203/480 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52198978; called by muse, mutect2, varscan2
- CTTNBP2 | c.4850G>C p.R1617T | Missense Mutation (SNP) | VAF 74/332 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV50407162; called by muse, mutect2, varscan2
- DAO | c.407G>T p.S136I | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as COSV99948433; called by muse, mutect2
- DDX42 | c.2572C>T p.R858W | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as rs533590615, COSV63790301; called by muse, mutect2, varscan2
- DNAH3 | c.10434T>G p.C3478W | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54526033; called by muse, mutect2, varscan2
- DNAH7 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100413823; called by muse, mutect2
- DSCAM | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as COSV68028085; called by muse, mutect2, varscan2
- EFR3A | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 130/280 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54458139; called by muse, mutect2, varscan2
- ERC1 | c.2479C>T p.Q827* (on ENST00000360905 / NM_178040.4; = p.Q799* on NM_178039.4) | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as rs753152606, COSV61695669; called by muse, mutect2, varscan2
- FAM24A | c.244T>C p.C82R | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV64405966; called by muse, mutect2, varscan2
- FAM98B | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV59842989; called by muse, mutect2, varscan2
- FLT1 | c.636T>A p.N212K | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.627); catalogued as COSV56729639; called by muse, mutect2, varscan2
- GPX6 | c.313G>T p.G105* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV62657724; called by muse, mutect2, varscan2
- HSPG2 | c.3184C>A p.Q1062K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV65972374, COSV65974140; called by muse, mutect2, varscan2
- INTS13 | c.106A>G p.N36D | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.257); catalogued as COSV53902990; called by muse, mutect2, varscan2
- KRT6B | c.292A>G p.S98G | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99360447; called by muse, varscan2
- LAMC2 | c.3544C>G p.P1182A | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51456225; called by mutect2, varscan2
- LASP1 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as COSV100530297; called by muse, mutect2
- LMBRD1 | c.1448C>T p.S483F (on ENST00000649011; = p.S461F on NM_018368.4) | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100992537, COSV65296787; called by muse, mutect2, varscan2
- LNX2 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV60336069; called by muse, mutect2, varscan2
- MADD | c.4262C>T p.A1421V | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs146118440; called by muse, mutect2, varscan2
- MEIS2 | c.232G>A p.D78N (on ENST00000561208 / NM_170675.5; = p.D65N on NM_002399.3) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV54937074; called by muse, mutect2, varscan2
- MTHFD1 | c.626G>C p.G209A | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53700939; called by muse, mutect2, varscan2
- MXRA5 | c.260A>C p.H87P | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54237698; called by muse, mutect2, varscan2
- NRP1 | c.1268G>C p.G423A | Missense Mutation (SNP) | VAF 48/498 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV55168492, COSV55170705; called by muse, mutect2
- NSG2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs147555850; called by muse, mutect2, varscan2
- OR4N5 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 83/400 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100374201, COSV61320719; called by muse, mutect2, varscan2
- OR9Q2 | c.314C>A p.T105N | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV61112058; called by muse, mutect2, varscan2
- PKD2L1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs193920845, COSV58399502; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1L1 | c.10984C>A p.P3662T | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV101005376; called by muse, mutect2
- PLAG1 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV100387706; called by muse, mutect2
- PLAGL2 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55788531; called by muse, mutect2, varscan2
- PLEKHG7 | c.1711A>C p.K571Q | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV100760034; called by muse, mutect2, varscan2
- PRDM9 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 22/133 reads (17%) | catalogued as COSV57003733, COSV57008674; called by muse, mutect2, varscan2
- PTCHD1 | c.1735A>G p.T579A | Missense Mutation (SNP) | VAF 68/435 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV65060448; called by muse, mutect2, varscan2
- ROR2 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as rs775860567, COSV65219730; called by muse, mutect2, varscan2
- RPH3A | c.1355G>A p.R452Q (on ENST00000389385 / NM_001143854.2; = p.R448Q on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs767497432, COSV66991337, COSV66991418; called by muse, mutect2, varscan2
- RRP12 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV59668175; called by muse, mutect2, varscan2
- RTL5 | c.1588dup p.Q530Pfs*83 | Frame Shift Ins (INS) | VAF 7/59 reads (12%) | catalogued as rs1474897273; called by mutect2, varscan2
- RTL5 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs1253620985, COSV65452956; called by muse, mutect2, varscan2
- SENP8 | c.525T>A p.C175* | Nonsense Mutation (SNP) | VAF 28/161 reads (17%) | catalogued as COSV61768032, COSV61768324; called by muse, mutect2, varscan2
- SHROOM3 | c.1917G>A p.W639* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV99933523; called by muse, mutect2, varscan2
- SLC34A2 | c.770G>C p.G257A | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV101158270, COSV65941784; called by muse, mutect2, varscan2
- SLC39A11 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs202154945, COSV55290302; called by muse, mutect2, varscan2
- SLC4A7 | c.2188C>G p.L730V | Missense Mutation (SNP) | VAF 43/514 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99839194; called by muse, mutect2
- SOX5 | c.641A>T p.E214V | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58632044; called by muse, mutect2, varscan2
- SRRM4 | c.1511T>G p.L504R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV57417872, COSV99938900; called by muse, mutect2, varscan2
- STAT1 | c.2200G>C p.V734L | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63116415; called by muse, mutect2, varscan2
- STK26 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs1469596591, COSV53746588; called by muse, mutect2, varscan2
- SVEP1 | c.10037G>A p.S3346N | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV52839976; called by muse, mutect2, varscan2
- TCF20 | c.5492C>G p.T1831S | Missense Mutation (SNP) | VAF 85/321 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV59491975; called by muse, mutect2, varscan2
- TDRD6 | c.2926T>C p.F976L | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV60176228; called by muse, mutect2, varscan2
- TENM1 | c.6870G>T p.E2290D | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.503); catalogued as COSV64433545; called by muse, mutect2, varscan2
- TRIM21 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV54344522; called by muse, mutect2, varscan2
- UBXN7 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 79/352 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV56355862; called by muse, mutect2, varscan2
- XIRP1 | c.1634G>C p.G545A | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61138855; called by muse, mutect2, varscan2
- ZFHX4 | c.7885A>C p.N2629H | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV50922859; called by muse, mutect2, varscan2
- ZFPM2 | c.982T>C p.F328L | Missense Mutation (SNP) | VAF 78/465 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV101022979; called by muse, mutect2, varscan2
- ZNF160 | c.445A>C p.T149P | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100762225; called by muse, mutect2
- ZNF214 | c.1621C>T p.L541F | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99547186; called by muse, mutect2
- ZNF329 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs45577535, COSV100798667; called by muse, mutect2, varscan2
- ZNF608 | c.1769A>T p.D590V | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV60438343; called by muse, mutect2, varscan2
- ADGRE4P | n.208C>T | Splice Region (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- C8orf76 | c.777_787del p.T260Sfs*35 | Frame Shift Del (DEL) | VAF 47/164 reads (29%) | called by mutect2, pindel, varscan2
- CPT1B | c.1350C>G p.N450K | Missense Mutation (SNP) | VAF 2/7 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2
- KDM6A | c.3157_3174del p.K1053_K1058del | In Frame Del (DEL) | VAF 36/182 reads (20%) | called by mutect2, pindel, varscan2
- OSBPL9 | c.348_360del p.Q117Rfs*13 | Frame Shift Del (DEL) | VAF 13/101 reads (13%) | called by mutect2, pindel, varscan2
- PDE6C | c.1208del p.A403Vfs*32 | Frame Shift Del (DEL) | VAF 40/277 reads (14%) | called by mutect2, pindel, varscan2
- SNX2 | c.1314_1351del p.N438Kfs*15 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel
- SYN3 | c.462_464del p.S154del | In Frame Del (DEL) | VAF 17/100 reads (17%) | called by pindel, varscan2
- TACC2 | c.6712del p.T2238Rfs*8 (on ENST00000334433; = p.T316Rfs*8 on NM_006997.4) | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by pindel, varscan2
- USP22 | c.613del p.L205Cfs*51 | Frame Shift Del (DEL) | VAF 25/68 reads (37%) | called by mutect2, pindel, varscan2
- ADAM32 | c.1170G>A p.P390= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as rs201298341, COSV65949958; called by muse, mutect2, varscan2
- ALMS1 | c.7872C>A p.A2624= | Silent (SNP) | VAF 59/265 reads (22%) | catalogued as COSV52511480; called by muse, mutect2, varscan2
- ANXA6 | c.189G>A p.K63= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs369346632, COSV100636773; called by muse, mutect2, varscan2
- CCDC171 | c.3163C>T p.L1055= | Silent (SNP) | VAF 21/298 reads (7%) | catalogued as rs1391854322, COSV99899876; called by muse, mutect2
- CCDC8 | c.699C>T p.S233= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs769220827, COSV56773635; called by muse, mutect2, varscan2
- EPRS1 | c.2595A>G p.K865= | Silent (SNP) | VAF 46/234 reads (20%) | catalogued as COSV65099358; called by muse, mutect2, varscan2
- FRMPD1 | c.2745C>T p.N915= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs1488612513, COSV66700615; called by muse, mutect2, varscan2
- GRID1 | c.1437C>T p.G479= | Silent (SNP) | VAF 84/414 reads (20%) | catalogued as COSV60032074; called by muse, mutect2, varscan2
- GSPT1 | c.198G>T p.P66= (on ENST00000420576 / NM_001130007.2; = p.P204= on NM_002094.4) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV70452705; called by muse, mutect2, varscan2
- HIPK2 | c.1812C>G p.S604= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as COSV61228213; called by muse, mutect2, varscan2
- HTT | c.1668G>A p.S556= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV61863165; called by muse, mutect2, varscan2
- INTS3 | c.2838A>T p.P946= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99669696; called by muse, mutect2
- IP6K1 | c.450G>A p.K150= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100391223, COSV58662764; called by muse, mutect2, varscan2
- MAGEA10 | c.555G>T p.L185= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV99726569; called by muse, mutect2
- NLRP9 | c.1971T>A p.P657= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as COSV60463925; called by muse, mutect2, varscan2
- PCDHB16 | c.507C>T p.N169= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV53363357; called by muse, mutect2, varscan2
- SULT6B1 | c.906G>A p.Q302= (on ENST00000535679 / NM_001367551.1; = p.Q264= on NM_001032377.2) | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99572981; called by muse, mutect2
- TET1 | c.3621T>G p.P1207= | Silent (SNP) | VAF 33/224 reads (15%) | catalogued as COSV65385289; called by muse, mutect2, varscan2
- TNPO3 | c.478C>A p.R160= | Silent (SNP) | VAF 43/181 reads (24%) | catalogued as rs752037576, COSV55282377; called by muse, mutect2, varscan2
- VDR | c.1104C>A p.R368= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs35435255, COSV99968542; called by muse, mutect2, varscan2
- ZNF835 | c.1398C>A p.I466= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs373727580, COSV73379486; called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888486 A>G | 3'Flank (SNP) | VAF 40/209 reads (19%) | catalogued as rs1350249824, COSV58045831; called by muse, mutect2, varscan2
- SNORD113-5 | n.8A>G | RNA (SNP) | VAF 32/164 reads (20%) | catalogued as rs565969072; called by muse, mutect2, varscan2
- ZFHX3 | c.-533+30A>G | Intron (SNP) | VAF 18/38 reads (47%) | catalogued as COSV73947911; called by muse, mutect2, varscan2
